Surgical pathology report (de-identified scan), TCGA case TCGA-N5-A4RN, project TCGA-UCS (Uterine Carcinosarcoma), tissue source site MSKCC, specimen TCGA-N5-A4RN-01A (Primary Tumor).

[page 1 of 3]
ICD O-3

Carcinosarcoma / Mixed
Mullerian Tumor, malignant
8956/3

Site: Endometrium C54.1
JW 4/2/13

Specimens Submitted:

- 1: Anterior abdominal wall (fs)
- 2: Uterus, cervix, bilateral fallopian tubes and ovaries
- 3: Small bowel adhesion
- 4: Left pelvic peritoneum
- 5: Sigmoid adhesion
- 6: Sentinel right hypogastric lymph node
- 7: Sentinel left external iliac lymph node
- 8: Left obturator lymph node
- 9: Omentum

DIAGNOSIS:

1. Anterior abdominal wall; biopsy - Metastatic carcinosarcoma, morphology similar to part #2.

2. Uterus, cervix, bilateral fallopian tubes and ovaries:

Tumor Type:

Carcinosarcoma (Malignant mullerian mixed tumor) of endometrium
with homologous differentiation
with components of small cell carcinoma and adenosarcoma

Myometrial Invasion:

(= < 50%)

Measures 5 mm in maximum depth

Myometrium thickness measures 18 mm in the area of maximal tumor

invasion

Endocervical Invasion:

Not identified

Lymphovascular invasion:

Identified
(extensive)

Endometrium:

Exhibits atrophy
Exhibits a polyp

Myometrium:

Exhibits adenomyosis
Exhibits multiple leiomyomata

Adnexa:

** Continued on next page **

[page 2 of 3]
[REDACTED]

Unremarkable

Comment: The immunohistochemical stains will be performed. The result will be reported in an addendum.

3. Small bowel adhesion; excision:
- Acute inflamed fibroadipose tissue with reactive mesothelial change.
4. Left pelvic peritoneum; biopsy:
- Benign fibroadipose tissue with reactive mesothelial change.
5. Colon, sigmoid adhesion; excision:
- Acute inflamed fibroadipose tissue with reactive mesothelial change.

6. Sentinel right hypogastric lymph node:
Lymph Node Dissection:
Benign lymph nodes
Number of lymph nodes examined: 1
-

7. Sentinel left external iliac lymph node:
Lymph Node Dissection:
Metastatic carcinosarcoma
Number of lymph nodes examined: 1
Number of lymph nodes with metastatic disease: 1
-

8. Left obturator lymph node:
Lymph Node Dissection:
Benign lymph nodes
Number of lymph nodes examined: 6
-

9. Omentum; omentectomy:
- Benign omentum with reactive mesothelium. No tumor seen.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

[REDACTED]

*** Report Electronically Signed Out *** [REDACTED]

[REDACTED]

[page 3 of 3]
[REDACTED]

Procedures/Addenda:
Addendum

[REDACTED]

Addendum Diagnosis

2. Uterus, cervix, bilateral fallopian tubes and ovaries; hysterectomy and salpingo-ooporectomy:
- Immunohistochemical stains provide support for a sizable component of small cell carcinoma of neuroendocrine type (positive for synaptophysin, chromogranin, negative for desmin and myogenin).

[REDACTED]

	Yes	No
W 12/31/12		
Primary		
Secondary		
tertiary		
Quaternary		
Quinary		
Sixth		
Seventh		
Eighth		
Ninth		
Tenth		
Eleventh		
Twelfth		
Thirteenth		
Fourteenth		
Fifteenth		
Sixteenth		
Seventeenth		
Eighteenth		
Nineteenth		
Twentieth		
Twenty-first		
Twenty-second		
Twenty-third		
Twenty-fourth		
Twenty-fifth		
Twenty-sixth		
Twenty-seventh		
Twenty-eighth		
Twenty-ninth		
Thirtieth		
Thirty-first		
Thirty-second		
Thirty-third		
Thirty-fourth		
Thirty-fifth		
Thirty-sixth		
Thirty-seventh		
Thirty-eighth		
Thirty-ninth		
Fortieth		
Forty-first		
Forty-second		
Forty-third		
Forty-fourth		
Forty-fifth		
Forty-sixth		
Forty-seventh		
Forty-eighth		
Forty-ninth		
Fiftieth		
Fifty-first		
Fifty-second		
Fifty-third		
Fifty-fourth		
Fifty-fifth		
Fifty-sixth		
Fifty-seventh		
Fifty-eighth		
Fifty-ninth		
Sixtieth		
Sixty-first		
Sixty-second		
Sixty-third		
Sixty-fourth		
Sixty-fifth		
Sixty-sixth		
Sixty-seventh		
Sixty-eighth		
Sixty-ninth		
Seventieth		
Seventy-first		
Seventy-second		
Seventy-third		
Seventy-fourth		
Seventy-fifth		
Seventy-sixth		
Seventy-seventh		
Seventy-eighth		
Seventy-ninth		
Eightieth		
Eighty-first		
Eighty-second		
Eighty-third		
Eighty-fourth		
Eighty-fifth		
Eighty-sixth		
Eighty-seventh		
Eighty-eighth		
Eighty-ninth		
Ninetieth		
Ninety-first		
Ninety-second		
Ninety-third		
Ninety-fourth		
Ninety-fifth		
Ninety-sixth		
Ninety-seventh		
Ninety-eighth		
Ninety-ninth		
One hundred		

BTU Date Reviewed: 12/26/12

Source: NCI Genomic Data Commons file 3246e9b5-962a-4868-9a01-2018a460e087 (TCGA-N5-A4RN.4A261649-F965-46BA-99A9-53AE715702ED.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).